Somatic mutation profile of tumor specimen BA2343D (aliquot aq-BA2343D) from BEATAML1.0 case 2336, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.4 years (28,636 days).
Specimen BA2343D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c397a0c-e95f-48ce-8276-47987239eadd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2185D (Solid Tissue Normal), aliquot aq-BA2185D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72adc625-0651-429a-b018-220bd0f71e03

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, 3'UTR 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 37/101 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPK2 | c.3256G>A p.V1086I | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs763412634; called by muse, mutect2, varscan2
- DGKI | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.343); catalogued as rs1356488881; called by muse, mutect2, varscan2
- LTBP2 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750926855, COSV56212028; called by muse, mutect2, varscan2
- TSR1 | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs763507991; called by muse, mutect2, varscan2
- CNR1 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- GNAI2 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- GSPT2 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- SLC17A9 | c.948C>A p.G316= | Splice Region (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- STAT2 | c.1813T>A p.S605T | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, varscan2
- CPA3 | c.819G>A p.R273= | Silent (SNP) | VAF 62/123 reads (50%) | catalogued as COSV56045574, COSV56047000; called by muse, mutect2, varscan2
- CRYGN | c.174G>A p.R58= | Silent (SNP) | VAF 71/152 reads (47%) | called by muse, mutect2, varscan2
- ERLEC1 | c.1026T>C p.S342= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- FN1 | c.2250C>T p.F750= | Silent (SNP) | VAF 8/139 reads (6%) | called by muse, mutect2
- FNDC3A | c.2283G>A p.Q761= (on ENST00000492622 / NM_001079673.2; = p.Q705= on NM_014923.5) | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, varscan2
- GOLGB1 | c.5262A>G p.E1754= | Silent (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- OSGIN2 | c.1311C>A p.I437= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- AK2 | c.*1716C>T | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
